Somatic mutation profile of tumor specimen 0DG87O from CCDI case PBBSHJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 2.2 years (809 days).
Specimen 0DG87O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1954f03-fd8d-425c-8480-98067b6c1db8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG84E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3df5e94-3e1b-449d-95a3-82de0895b7ba

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Intron 3, 3'UTR 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NLRP3 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 359/432 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs151344629, CM021072; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.808T>G p.F270V | Missense Mutation (SNP) | VAF 324/357 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- HMGB2 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 520/1225 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs754458539, COSV99632944; called by muse, mutect2, varscan2
- KLC1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 24/579 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1210354192; called by muse, mutect2
- OBSCN | c.6616C>T p.R2206W | Missense Mutation (SNP) | VAF 166/408 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs552121194; called by muse, mutect2, varscan2
- ROCK1 | c.3977G>A p.R1326H | Missense Mutation (SNP) | VAF 802/1862 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs754629412; called by muse, mutect2, varscan2
- C20orf27 | c.74G>A p.G25E (on ENST00000379772 / NM_001258429.2; = p.G50E on NM_001039140.3) | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.238); called by muse, mutect2
- CASZ1 | c.4805A>T p.E1602V | Missense Mutation (SNP) | VAF 183/408 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- FAT3 | c.5565C>A p.D1855E | Missense Mutation (SNP) | VAF 444/525 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTPBP6 | c.1548_*17del | Nonstop Mutation (DEL) | VAF 140/380 reads (37%) | called by mutect2, varscan2
- MPDZ | c.1424A>T p.D475V | Missense Mutation (SNP) | VAF 62/1065 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- OTOGL | c.3196G>T p.V1066F (on ENST00000547103; = p.V1057F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 523/1287 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PCDH15 | c.2678C>G p.T893S | Missense Mutation (SNP) | VAF 511/1270 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PTPRQ | c.6429C>T p.I2143= (on ENST00000616559; = p.I2110= on NM_001145026.2) | Splice Region (SNP) | VAF 592/1541 reads (38%) | called by muse, mutect2, varscan2
- SULT2A1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 290/332 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- ACTN2 | c.2349T>A p.I783= | Silent (SNP) | VAF 113/1098 reads (10%) | called by muse, mutect2, varscan2
- GIMAP6 | c.369C>G p.P123= | Silent (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- SCN4A | c.858G>A p.P286= | Silent (SNP) | VAF 110/123 reads (89%) | catalogued as rs560230431, COSV71129922; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CISD2 | c.104-48_104-42del | Intron (DEL) | VAF 175/364 reads (48%) | called by mutect2, varscan2
- GPM6A | c.37+65G>A | Intron (SNP) | VAF 361/761 reads (47%) | catalogued as rs11732859; called by muse, mutect2, varscan2
- MAP3K10 | c.1435+92T>C | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- POMGNT2 | c.*29G>T | 3'UTR (SNP) | VAF 11/127 reads (9%) | called by muse, mutect2, varscan2
